Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7785, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7785-01A (Primary Tumor).

ear-old male with a history of PSA value of 4.3. The patient also has a history of biopsy on this biopsy reveals: Poorly differentiated prostatic adenocarcinoma Gleason score 3+4 = 7 in the right portion. The patient also has a history of tonsillectomy, hypertension, and hypercholesterolemia.
PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Radical prostatectomy.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION –

FOUR LYMPH NODES, NEGATIVE FOR CARCINOMA (0/4).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION –

THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES WITH PREDOMINANT INVOLVEMENT OF THE RIGHT LOBE, AND HAS A GREATEST NODULAR DIAMETER OF 1.9 CM.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 10% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE RIGHT POSTERIOR MID AND RIGHT POSTERIOR BASE REGIONS (SLIDES 3V AND 3W).
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- G. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- H. PERINEURAL INVASION IS IDENTIFIED.
- I. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- J. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- K. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- L. TNM HISTOLOGIC GRADE = G3-4.
- M. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC PROSTATITIS WITH ATROPHIC CHANGES ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 4.3
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	20%
WEIGHT OF PROSTATE:	45.45gm
TUMOR SIZE:	Maximum dimension: 1.9 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	7
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 42ce542d-86ad-4459-b3fb-c0239f7bc1f7 (TCGA-EJ-7785.01ED5C8E-64F0-4E58-BD52-92A0D4F4AF2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).